Somatic mutation profile of tumor specimen TCGA-17-Z037-01A (aliquot TCGA-17-Z037-01A-01W-0746-08) from TCGA case TCGA-17-Z037, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z037-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69e45844-c39e-4ab9-a09d-8e20273a5bb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z037-11A (Solid Tissue Normal), aliquot TCGA-17-Z037-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c603ba75-bf42-4ee3-bee4-ac848fdf7cd2

The open-access MAF lists 145 somatic variants for this specimen: 110 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 34, Nonsense Mutation 7, Frame Shift Del 4, Splice Region 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4463del p.L1488Yfs*19 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | catalogued as rs1114167577, COSV57389473; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FBN1 | c.2153C>T p.T718M | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs777526851, COSV57308043, COSV57316057; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 24/188 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 5/16 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ABCC8 | c.1630+1G>A p.X544_splice | Splice Site (SNP) | VAF 14/74 reads (19%) | catalogued as rs773306994, CS051239, CS113483, CS982375; called by muse, mutect2, varscan2
- ABCG1 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 42/242 reads (17%) | catalogued as rs577566323, COSV59208909; called by muse, mutect2, varscan2
- ACHE | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs148991713; called by muse, mutect2, varscan2
- ADAMTS5 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1178827544; called by muse, mutect2, varscan2
- ANO5 | c.411G>C p.W137C | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61082965; called by muse, mutect2
- ARHGEF6 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs942797542; called by muse, mutect2, varscan2
- BFAR | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs547915921, COSV99902081; called by muse, mutect2, varscan2
- BRIX1 | c.676G>C p.D226H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100331413; called by muse, mutect2, varscan2
- CACNA1S | c.2467C>T p.R823W | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs199758244, COSV100754582, COSV62945723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPRIN2 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 54/304 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs763676110, COSV51830525; called by muse, varscan2
- CCDC39 | c.633A>C p.Q211H | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99870681; called by muse, mutect2, varscan2
- CD226 | c.128G>C p.G43A | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.038); catalogued as COSV54613972; called by muse, mutect2, varscan2
- CDC37 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs758820884; called by muse, mutect2, varscan2
- CDH10 | c.40G>C p.V14L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100051611; called by muse, mutect2, varscan2
- CPO | c.104A>C p.K35T | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as COSV55939850; called by muse, mutect2, varscan2
- CPXM2 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0.025); catalogued as rs370358833; called by muse, mutect2, varscan2
- CTDSPL | c.796G>A p.V266M (on ENST00000273179 / NM_001008392.2; = p.V255M on NM_005808.3) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs566199681; called by muse, mutect2, varscan2
- CTPS2 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781314454; called by muse, mutect2, varscan2
- CYB5RL | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs767771861; called by muse, mutect2, varscan2
- DNAH11 | c.6118C>T p.R2040C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs199772877; called by muse, mutect2, varscan2
- FAM71E1 | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); catalogued as COSV58542475; called by muse, mutect2, varscan2
- FAT3 | c.8024C>T p.S2675L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV53094091, COSV53094990; called by muse, mutect2
- IKZF5 | c.680A>G p.Y227C | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); catalogued as rs1323716493; called by muse, mutect2, varscan2
- IL1RAPL2 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61146324; called by muse, mutect2, varscan2
- KCNT2 | c.3031C>T p.R1011W | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760737863, COSV54064723; called by muse, mutect2, varscan2
- KRT34 | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 103/273 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs754958901; called by muse, mutect2, varscan2
- LINGO4 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs143135535; called by muse, mutect2, varscan2
- LRP1 | c.9853C>T p.R3285C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1327544994; called by muse, mutect2, varscan2
- MAST2 | c.3095C>T p.S1032F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as rs1205798500; called by muse, mutect2, varscan2
- MDN1 | c.4090G>A p.V1364M | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs114853466; called by muse, mutect2, varscan2
- MFAP3L | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs972243484, COSV64371980; called by muse, mutect2
- MMS22L | c.2078A>G p.D693G | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1448312348; called by muse, mutect2, varscan2
- MYOF | c.876C>T p.G292= | Splice Region (SNP) | VAF 16/70 reads (23%) | catalogued as rs181979817; called by muse, mutect2, varscan2
- NEK11 | c.1897A>T p.I633F | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs749060904; called by muse, mutect2
- OR2G6 | c.831C>G p.F277L | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV58573998; called by muse, mutect2
- OR2M7 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs143090101, COSV58740084; called by muse, mutect2, varscan2
- OR51I2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs746240729, COSV58298444; called by muse, mutect2, varscan2
- PCARE | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); catalogued as rs778162481, COSV59057893, COSV59058134; called by muse, mutect2, varscan2
- PCDHB11 | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | catalogued as rs1554285839, COSV61311264; called by muse, mutect2
- PCLO | c.7862C>T p.S2621F | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV61642916; called by muse, mutect2, varscan2
- PEX11B | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs200193500; called by muse, mutect2, varscan2
- PRSS35 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs769349887, COSV63801404; called by muse, mutect2, varscan2
- RAB6B | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs201627683, COSV99558360; called by muse, mutect2, varscan2
- RASGRF2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs746029332; called by muse, mutect2
- SCN9A | c.140del p.P47Qfs*43 | Frame Shift Del (DEL) | VAF 22/142 reads (15%) | catalogued as rs1281216048, COSV100314977; called by mutect2, pindel, varscan2
- SEMA3A | c.934T>C p.F312L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1453444768; called by muse, mutect2, varscan2
- SLC8A1 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs774920726, COSV60469946; called by muse, mutect2, varscan2
- SYNE1 | c.7444G>T p.V2482F (on ENST00000367255 / NM_182961.4; = p.V2489F on NM_033071.3) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.668); catalogued as COSV55119339; called by muse, mutect2, varscan2
- TRIP12 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.14); catalogued as rs1375231368; called by muse, mutect2, varscan2
- TSHZ1 | c.3151G>A p.A1051T (on ENST00000580243 / NM_001308210.2; = p.A1006T on NM_005786.6) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769332406; called by muse, mutect2, varscan2
- USH2A | c.7168G>A p.G2390R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as rs376983577, CM149922; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ZNF157 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs761809026, COSV65658941; called by muse, mutect2
- ZNF774 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs760990088, COSV62979582; called by muse, mutect2
- ADGRL2 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- AK7 | c.1076A>G p.Y359C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ATP5F1A | c.1179C>A p.I393= | Splice Region (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- CARD6 | c.2257A>T p.M753L | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBLB | c.1019A>G p.D340G | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC170 | c.425A>G p.E142G | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, mutect2
- CENPC | c.1855G>T p.E619* | Nonsense Mutation (SNP) | VAF 18/128 reads (14%) | called by muse, mutect2, varscan2
- CFHR3 | c.670T>A p.F224I | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CP | c.836A>T p.D279V | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- DLD | c.1118G>A p.C373Y | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DNAH11 | c.10892T>G p.L3631R | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2
- DSP | c.6236A>C p.D2079A | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.396); called by muse, mutect2
- FAT2 | c.10468A>G p.S3490G | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.078); called by muse, mutect2
- FDFT1 | c.377C>A p.P126Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.526); called by muse, mutect2
- GART | c.570A>C p.E190D | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GEMIN8 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, varscan2
- GPR65 | c.952del p.Q318Kfs*16 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- GRAMD1C | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- KAT2A | c.1607A>T p.K536M | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2
- KBTBD6 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- KIAA1109 | c.7786A>T p.R2596* | Nonsense Mutation (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- LOXL4 | c.1693C>T p.L565F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGI1 | c.1666T>G p.Y556D | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MXRA5 | c.2367A>C p.K789N | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- NAALAD2 | c.1214C>A p.T405N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NEIL3 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- NETO1 | c.248A>C p.Y83S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NMUR2 | c.563A>T p.K188M | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PGAM4 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PIGL | c.389T>G p.V130G | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- PRDM2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PRICKLE3 | c.1256C>A p.A419D | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- PTCHD1 | c.2498T>A p.V833D | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2
- PTPRC | c.437C>A p.S146* | Nonsense Mutation (SNP) | VAF 34/217 reads (16%) | called by muse, mutect2, varscan2
- PTPRE | c.679T>C p.S227P | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- PTPRN | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCMH1 | c.541C>T p.P181S (on ENST00000326197 / NM_001031694.2; = p.P134S on NM_012236.4) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- SCN8A | c.5750G>T p.C1917F | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK6 | c.204A>T p.Q68H | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMC2 | c.1457C>G p.S486C | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); called by muse, mutect2
- TBX15 | c.585A>T p.R195S (on ENST00000369429 / NM_001330677.2; = p.R89S on NM_152380.3) | Missense Mutation (SNP) | VAF 55/295 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCERG1L | c.1753del p.M585* | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- TLCD1 | c.335G>C p.W112S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, varscan2
- TMEM131L | c.2240C>T p.S747F | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TRAPPC12 | c.1382A>C p.Y461S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- TRIM3 | c.1501G>A p.V501M | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- TTK | c.2477T>G p.L826W | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- UMODL1 | c.968T>A p.V323D | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- WNK3 | c.762C>A p.C254* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- ZFP82 | c.670A>T p.K224* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- ZNF260 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF510 | c.798G>T p.K266N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); called by mutect2, varscan2
- ADAMTS18 | c.3081C>T p.P1027= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs373173918; called by muse, mutect2, varscan2
- AIM2 | c.771T>C p.T257= | Silent (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- BCL2L1 | c.240G>C p.V80= | Silent (SNP) | VAF 13/99 reads (13%) | called by mutect2, varscan2
- CELSR2 | c.5562C>T p.T1854= | Silent (SNP) | VAF 22/124 reads (18%) | called by muse, mutect2, varscan2
- CHRM2 | c.756C>T p.D252= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs531986911, COSV57765140, COSV57779856; called by muse, mutect2, varscan2
- DAPK1 | c.3168G>A p.A1056= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs193150601; called by muse, mutect2, varscan2
- DAW1 | c.435T>G p.P145= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- DSCAM | c.1380G>A p.T460= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs1455755847, COSV68023126; called by muse, mutect2, varscan2
- ERCC6L | c.3612A>G p.V1204= | Silent (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- F13A1 | c.195C>T p.H65= | Silent (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- FCRL3 | c.1965T>C p.P655= | Silent (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- FRMPD1 | c.3990G>A p.G1330= | Silent (SNP) | VAF 47/165 reads (28%) | called by muse, mutect2, varscan2
- GRIA2 | c.2376A>G p.G792= | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- KRT6C | c.636G>A p.P212= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs147574610; called by muse, mutect2, varscan2
- LZTR1 | c.708C>T p.C236= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- MAMLD1 | c.948G>A p.G316= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as rs1557406325; called by muse, mutect2, varscan2
- MTHFD1L | c.735C>T p.S245= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV66209011; called by muse, mutect2, varscan2
- MYO10 | c.3528G>A p.P1176= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs1171822684; called by muse, mutect2, varscan2
- NLRP5 | c.1092C>T p.F364= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs1414563064, COSV66762803; called by muse, mutect2, varscan2
- NOTCH2 | c.522C>T p.F174= | Silent (SNP) | VAF 38/110 reads (35%) | called by muse, mutect2, varscan2
- OR2T27 | c.819T>C p.A273= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV61283070; called by muse, mutect2, varscan2
- OR52B2 | c.27C>T p.F9= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as rs1280857659; called by muse, mutect2
- OXR1 | c.2565T>C p.R855= (on ENST00000442977 / NM_001198532.1; = p.R827= on NM_018002.3) | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs1308835836, COSV99860900; called by muse, mutect2, varscan2
- PREX2 | c.4617C>T p.S1539= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs772004397, COSV55800320; called by muse, varscan2
- PTCHD1 | c.2499C>A p.V833= | Silent (SNP) | VAF 4/88 reads (5%) | called by muse, mutect2
- RXFP3 | c.417G>A p.A139= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs778126882, COSV57504950; called by muse, mutect2, varscan2
- SDHA | c.1299C>T p.P433= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs144473374; ClinVar: likely benign; called by muse, mutect2, varscan2
- SH2D2A | c.600C>T p.T200= | Silent (SNP) | VAF 172/553 reads (31%) | catalogued as rs201744993, COSV63884859; called by muse, mutect2, varscan2
- SIM1 | c.1251G>A p.P417= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs1182837670, COSV53490766; called by muse, mutect2, varscan2
- SLC6A2 | c.159G>A p.A53= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs750613505, COSV54916127; called by muse, mutect2, varscan2
- SLFN11 | c.1125T>C p.P375= | Silent (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- SMG1 | c.945T>C p.F315= | Silent (SNP) | VAF 29/129 reads (22%) | called by muse, mutect2, varscan2
- THSD7B | c.1815C>T p.S605= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs143921844; called by muse, mutect2, varscan2
- UNC79 | c.2313G>A p.P771= (on ENST00000393151 / NM_001346218.2; = p.P594= on NM_020818.5) | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as rs756878081; called by muse, mutect2, varscan2
- LINC01565 | n.1147C>T | RNA (SNP) | VAF 13/74 reads (18%) | catalogued as rs201887104; called by muse, varscan2
